Surgical pathology report (de-identified scan), TCGA case TCGA-66-2756, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2756-01A (Primary Tumor).

[page 1 of 2]
Examination report

Macroscopic findings:

1. (a-m) Left superior pulmonary lobe: resected lobe weighing 634g, and measuring 240 x 130 x 60 mm, with remnants of pleural adhesion and, adhering tightly to the hilar section, a pericardial lobe measuring 75 x 50 mm, with slightly whitish thickening and subhemorrhaging. In S 3 there is grayish-white, brittle, yellowish necrosis and anthracotic pigment including a polycyclic, well demarcated tumor, measuring 75 x 50 x 95 mm, extending under the pericardial lobe described and, with unclear demarcation, to the adjacent subpleural and mediastinal adipose tissue. B3 is tumorous in the intermediary section and destructed. The remaining segmental bronchi, which can be dissected up to the periphery, are unremarkable. In the hilar section there are anthracotic pigmented and swollen, non-tumorous lymph nodes. In the peritumoral pulmonary tissue there is a golden-yellow, mesh-like parenchymal image (xanthomatous retention pneumonia?) and in S 1, accentuated in the apical section, there is clear pulmonary emphysema with a coarse structure and possible honeycomb lung.
2. Phrenic nerve: Grayish-brown, restiform excised material, 6 mm in length.
3. (a-b) Aortopulmonary window: bipartite lymph adipose tissue, measuring 25 x 20 x 10 mm in total, with anthracotic pigmented lymph nodes, which are also in parts swollen and display adipose tissue. Complete embedment.
4. L 11: quadripartite, measuring almost 10 mm in total, blackish pigmented lymph node tissue.
5. L 9: bipartite measuring 6 mm in total, blackish pigmented lymph node tissue.
6. L 7: segmented, measuring 5 mm in total, blackish pigmented lymph node tissue.

Microscopic findings:

1. (HE, PAS, EvG) tumor-free bronchial wall in the instantaneous section and the subsequent paraffin embedment in the bronchial resection margin. Immediately next to this there are numerous lymph nodes, some with significant anthracotic pigment, with sinus histiocytosis and lymphofollicular hyperplasia as well as acute blood clotting. The described tumor, made up of solid and garland-shaped structures of large, pleomorphic cells with a significantly misaligned nucleoplasmic ratio, chromatin coarsening and frequent mitosis with multiple necrotic inclusions and concomitant stromal desmoplasia without keratinizing growth. Penetration of the mediastinal pleura with intrusion, starting focally, into the lipomatous-atrophic thymus tissue. The adjacent pericardial lobe is still tumor-free and there are further small non-tumorous lymph nodes embedded in the mediastinal adipose tissue. In the apical section of S1 there is a subpleural area of scarring with fibroelastosis and nearby, a significantly bullous and emphysematous lung structure with rarefied, stubby, upright and partially inflamed alveolar septa. In the peritumoral, intraalveolar area there is a partly compact build-up of foamy cellular macrophages.
2. (HE) tumor-free lymph node tissue with slight lymphofollicular hyperplasia.
3. (HE) Similar findings to 2 with additional prominent histiocytosis and anthracosis
4. (HE) Similar findings to 3
5. (HE) Similar findings to 3
6. (HE) Similar findings to 3

[page 2 of 2]
Diagnosis: Resected left superior pulmonary lobe, measuring a max. of 95 mm, poorly differentiated and nonkeratinizing squamous cell carcinoma with intrusion into the mediastinum and infiltration here of the lipomatous thymus tissue; next to this is a non-tumorous pericardial lobe, non-tumorous bronchial resection margins and non-tumorous lymph nodes with anthracotic pigment in the hilar and intrapulmonary sections. Pre-existing more severe, destructive pulmonary emphysema with structural sclerosis; xanthomatous retention pneumonia in the immediate peritumorous section due to nicotine abuse.

2. ? 6. Further, tumor-free lymph nodes with varying degrees of anthracotic pigmentation.

Assessment:

The outer resection layers are all tumor-free on all sides and after that unequivocal removal of the carcinoma.

Tumor classification:

M-8070/3, G 3, pT 4, pN 0, pMX, stage III B. R 0.

Left superior pulmonary lobe

Lymph nodes

Source: NCI Genomic Data Commons file 2a95031c-052c-49c7-a28f-b879563da3bb (TCGA-66-2756.1AC41670-2AAF-428F-B8B5-D257951E6F5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).